Gene-level copy-number profile of specimen HCM-BROD-0555-C15-85M from HCMI case HCM-BROD-0555-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 48.2 years (17,601 days).
Specimen HCM-BROD-0555-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d9a656ba-049d-4e97-84f8-84dc1befae3b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0555-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/9237003e-1e22-446c-8397-1f4f3812d37f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 472; copy number 1: 737; copy number 2: 27,828; copy number 3: 21,327; copy number 4: 7,143; copy number 5: 199; copy number 6: 457; copy number 7: 140; copy number 8: 2; copy number 10: 342; copy number 13: 62; copy number 14: 1; copy number 15: 7; copy number 16: 13; copy number 20: 48; copy number 21: 5; copy number 23: 54; copy number 29: 62; copy number 31: 14.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,695,176–22,029,594, 10 genes (within-gene range 0–2): KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,406 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:86,643,914–103,989,658, 404 genes, copy number 10–13 (broad region; genes not listed).
- chr7:113,415,689–114,075,920, 3 genes, copy number 20: AC073137.1, AC073348.1, PPP1R3A.
- chr7:115,503,367–117,715,971, 54 genes, copy number 23 (within-gene range 2–23): POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1.
- chr8:46,028,804–56,656,496, 162 genes, copy number 5–6 (broad region; genes not listed).
- chr8:71,155,454–85,220,421, 198 genes, copy number 6–7 (broad region; genes not listed).
- chr8:86,866,415–89,415,071, 15 genes, copy number 6: CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, RPSAP74, KRT8P4.
- chr8:105,826,570–105,929,238, 2 genes, copy number 6: AC090802.1, Y_RNA.
- chr8:115,950,511–116,325,062, 1 gene, copy number 6 (within-gene range 4–6): LINC00536.
- chr8:116,289,622–122,428,551, 63 genes, copy number 6 (broad region; genes not listed).
- chr8:122,485,515–122,489,815, 1 gene, copy number 6: AC108136.1.
- chr8:124,973,295–135,456,952, 139 genes, copy number 7 (broad region; genes not listed).
- chr8:140,505,813–145,066,685, 197 genes, copy number 5–8 (broad region; genes not listed).
- chr12:18,683,169–27,161,393, 133 genes, copy number 14–29 (broad region; genes not listed).
- chr12:44,508,275–45,610,620, 14 genes, copy number 31: NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6.
- chr14:103,148,597–103,241,972, 6 genes, copy number 5: RPL21P12, GCSHP2, LINC00605, AL161669.2, AL161669.3, RPL21P13.
- chr17:75,721,328–75,757,818, 1 gene, copy number 5 (within-gene range 4–5): ITGB4.
- chr17:81,822,361–81,881,106, 9 genes, copy number 5: MCRIP1, PPP1R27, P4HB, AC145207.3, AC145207.9, AC145207.2, ARHGDIA, AC145207.5, AC145207.6.
- chr17:82,228,397–82,261,129, 1 gene, copy number 5 (within-gene range 4–5): SLC16A3.
- chr17:82,239,023–82,273,731, 3 genes, copy number 5: CSNK1D, AC132872.3, AC132872.4.

Autosomal genes at a single copy (total copy number 1): 737. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
